FM case AD3440 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/7cacb39c-00cb-46ca-b36d-4c095a36d615

Male, 49.7 years: Gastrointestinal stromal tumor, NOS (ICD-O-3 8936/1) of the gastrointestinal tract; metastasis biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
